Gene-level copy-number profile of tumor specimen TCGA-77-7142-01A from TCGA case TCGA-77-7142, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.7 years (21,796 days).
Specimen TCGA-77-7142-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0c122b06-375d-41fd-85c5-02d55af2fbc3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-7142-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ec7c9b05-c6d0-44f5-8c5e-7c4a5bb63208

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 576; copy number 2: 17,126; copy number 3: 15,238; copy number 4: 15,702; copy number 5: 3,730; copy number 6: 3,975; copy number 7: 792; copy number 8: 965; copy number 9: 966; copy number 10: 38; copy number 11: 14; copy number 12: 5; copy number 15: 498; copy number 17: 121.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-7142-01A-11D-2041-01): tumor purity 0.39, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,208,082–141,208,376, 1 gene: RPS16P3.
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–2): FOCAD.
- chr9:20,716,105–23,438,700, 62 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,284 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:166,691,187–198,222,513, 619 genes, copy number 15–17 (broad region; genes not listed).
- chr5:180,226,378–181,217,864, 43 genes, copy number 9: AC104115.1, MAPK9, AC104115.2, AC008610.1, GFPT2, AC034213.1, RNU6-525P, CNOT6, AC122714.1, SCGB3A1, FLT4, AC122714.2, LINC02222, OR2AI1P, RNU1-17P, OR2Y1, MGAT1, AC022413.1, HEIH, LINC00847, AC022413.2, ZFP62, BTNL8, Y_RNA, RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P, BTNL9, MIR8089, AC008620.1, FOXO1B, AC008620.2, OR2V1, OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, AC008443.7.
- chr7:82,754,012–86,217,733, 21 genes, copy number 9–11 (within-gene range 5–11): PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1.
- chr12:66,767–20,753,386, 590 genes, copy number 9 (broad region; genes not listed).
- chr16:27,158,451–27,176,587, 1 gene, copy number 10: LINC02129.
- chr20:15,552,157–16,586,693, 9 genes, copy number 9: AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1.
- chr22:34,756,676–35,002,862, 1 gene, copy number 11 (within-gene range 3–11): LINC02885.

Autosomal genes at a single copy (total copy number 1): 576. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
